Gene-level copy-number profile of tumor specimen TCGA-2H-A9GK-01A from TCGA case TCGA-2H-A9GK, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 44.0 years (16,067 days).
Specimen TCGA-2H-A9GK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.d8b6df0e-9fd1-4042-ad12-5a0794c33d3e.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2H-A9GK-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 391 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1202b428-8db8-422b-b380-4973222d5250

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3,118; copy number 1: 7,087; copy number 2: 25,078; copy number 3: 19,035; copy number 4: 4,376; copy number 5: 305; copy number 6: 523; copy number 7: 329; copy number 8: 62; copy number 9: 1; copy number 11: 230; copy number 12: 69; copy number 16: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2H-A9GK-01A-11D-A37B-01): tumor purity 0.47, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 214 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene (within-gene range 0–2): RSRP1.
- chr1:25,266,102–25,337,465, 4 genes: AL031432.2, RHD, SDHDP6, AL928711.1.
- chr2:38,814–46,870, 1 gene: FAM110C.
- chr2:241,227,264–241,494,841, 6 genes (within-gene range 0–2): HDLBP, SEPTIN2, AC104841.1, AC005104.1, FARP2, AC005104.2.
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr9:13,738,537–14,069,417, 6 genes: AL158157.1, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3.
- chr11:55,635,113–55,652,854, 2 genes: OR4P4, OR4S2.
- chr15:19,878,555–23,447,243, 169 genes (broad region; genes not listed).
- chr18:50,560,087–52,339,025, 23 genes (within-gene range 0–3): MAPK4, AC012433.2, AC012433.1, MRO, HNRNPA3P16, RPL17P46, ME2, Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1, RPS8P3, AC016383.3, AC016383.2, AC016383.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,537 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:119,533,749–121,463,508, 52 genes, copy number 7 (within-gene range 3–7): GAPDHP32, HSD3BP3, GAPDHP27, HSD3BP4, GAPDHP33, LINC00622, HSD3BP5, ZNF697, PHGDH, HMGCS2, REG4, NBPF7, PFN1P9, NOTCH2P1, ADAM30, NOTCH2, AC245008.1, RNU6-465P, SEC22B, AC244669.2, 7SK, AC244669.1, U1, NBPF8, PFN1P2, AC241952.1, U2, 7SK, NOTCH2NLR, NBPF26, AC253572.1, RNVU1-19, PPIAL4A, AC241377.3, LINC00623, RNVU1-4, AC241377.4, AC241377.2, U1, AC241377.1, FCGR1B, AC244453.3, AC244453.2, H2BP1, AC244453.1, H3P4, RPL22P6, FAM72B, SRGAP2C, AC243994.1, SRGAP2-AS1, LINC02798.
- chr1:153,373,711–154,580,013, 86 genes, copy number 5 (broad region; genes not listed).
- chr1:157,513,377–158,494,886, 34 genes, copy number 5: FCRL5, FCRL4, AL135929.2, AL135929.1, FCRL3, AL356276.1, AL356276.2, VDAC1P9, FCRL2, FCRL1, CD5L, MRPS21P2, AL139010.1, KIRREL1, KIRREL1-IT1, SMIM42, LINC01704, ELL2P1, CD1D, AL138899.2, AL138899.1, CD1A, HMGN1P5, CD1C, CD1B, CD1E, OR10T2, OR10K2, OR10T1P, EI24P2, OR10K1, OR10R2, AL365440.1, OR10R3P.
- chr2:3,603,397–3,604,242, 1 gene, copy number 9: AC010907.2.
- chr3:84,638,405–86,125,287, 10 genes, copy number 8: LINC00971, AC117482.1, LINC02025, AC132660.2, CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1.
- chr3:158,496,561–198,222,513, 704 genes, copy number 6–7 (within-gene range 1–7) (broad region; genes not listed).
- chr5:151,378,003–151,382,381, 2 genes, copy number 5: AC034205.1, AC034205.3.
- chr6:36,737,050–53,924,125, 370 genes, copy number 8–16 (within-gene range 8–17) (broad region; genes not listed).
- chr8:132,685,007–132,760,712, 1 gene, copy number 5 (within-gene range 4–5): TMEM71.
- chr8:132,775,358–135,742,495, 50 genes, copy number 5: PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2, AC105180.2, AC105180.1, ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1, AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56, LINC01591, AC040914.1, KHDRBS3, MAPRE1P1, RNU1-35P.
- chr8:135,977,329–136,295,232, 2 genes, copy number 5: AC103955.1, AC023781.1.
- chr15:68,184,032–72,602,987, 95 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr15:73,683,966–76,905,444, 129 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr18:29,629,842–29,650,440, 1 gene, copy number 5: AC117569.2.

Autosomal genes at a single copy (total copy number 1): 7,054. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
